Somatic mutation profile of tumor specimen MBCProject_5927_T1_WES (aliquot MBCProject_5927_T1_WES_1) from CMI case MBCProject_5927, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 42.2 years (15,405 days).
Specimen MBCProject_5927_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9fe22fba-e6f3-4ab9-ab4e-c9b319159066.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_5927_SALIVA (Saliva), aliquot MBCProject_5927_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f94c550c-d7f6-4e99-b0ab-8d095cc92cfa

The open-access MAF lists 28 somatic variants for this specimen: 13 protein-altering or splice-affecting, 5 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Intron 6, Silent 5, Frame Shift Del 2, 3'UTR 2, 3'Flank 1, Splice Site 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 12/61 reads (20%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- RAD50 | c.2165del p.K722Rfs*14 | Frame Shift Del (DEL) | VAF 10/62 reads (16%) | catalogued as rs397507178, COSV54758496; ClinVar: pathogenic; called by mutect2, varscan2
- AJM1 | c.1832G>A p.R611H | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs1299451782; called by muse, mutect2
- CHAF1B | c.224C>T p.S75F | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100023726; called by muse, mutect2, varscan2
- COBLL1 | c.2834del p.L945Cfs*12 (on ENST00000392717; = p.L907Cfs*12 on NM_014900.5) | Frame Shift Del (DEL) | VAF 8/34 reads (24%) | catalogued as rs374805044; called by mutect2, varscan2
- SYNE1 | c.4540G>C p.V1514L (on ENST00000367255 / NM_182961.4; = p.V1521L on NM_033071.3) | Missense Mutation (SNP) | VAF 7/76 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV54922424, COSV54942690; called by muse, varscan2
- TNKS2 | c.521-1G>T p.X174_splice | Splice Site (SNP) | VAF 9/71 reads (13%) | catalogued as rs1349333017; called by muse, varscan2
- TUBAL3 | c.1093C>T p.R365W | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.417); catalogued as rs1420803969, COSV100990454; called by muse, mutect2, varscan2
- BCORL1 | c.1601G>A p.S534N | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.017); called by mutect2, varscan2
- H2BC3 | c.151C>T p.P51S | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- LRRTM4 | c.169G>A p.E57K | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (0.71); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- POLH | c.724T>G p.S242A | Missense Mutation (SNP) | VAF 25/93 reads (27%) | SIFT tolerated (0.28); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- TAF6 | c.1127C>T p.S376F | Missense Mutation (SNP) | VAF 13/93 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- FAM71E1 | c.462C>T p.S154= (on ENST00000600100 / NM_001308429.2; = p.S138= on NM_138411.3) | Silent (SNP) | VAF 4/37 reads (11%) | called by muse, mutect2
- PIK3CD | c.15G>A p.V5= | Silent (SNP) | VAF 10/62 reads (16%) | called by muse, varscan2
- POLR3A | c.3693C>T p.N1231= | Silent (SNP) | VAF 7/79 reads (9%) | called by muse, mutect2, varscan2
- RTKN2 | c.1278A>G p.S426= | Silent (SNP) | VAF 8/56 reads (14%) | called by muse, varscan2
- SLC1A3 | c.204C>T p.L68= | Silent (SNP) | VAF 6/82 reads (7%) | called by muse, mutect2
- CHN1 | c.*582_*583dup | 3'UTR (INS) | VAF 6/23 reads (26%) | called by mutect2, pindel, varscan2
- DCUN1D4 | c.616-2096G>C | Intron (SNP) | VAF 8/81 reads (10%) | called by muse, mutect2, varscan2
- FAM53C | c.136+19T>G | Intron (SNP) | VAF 4/36 reads (11%) | catalogued as rs1390623498; called by mutect2, varscan2
- SET | c.113-1605del | Intron (DEL) | VAF 6/30 reads (20%) | catalogued as rs757604683; called by mutect2, varscan2
- SH3GLB2 | c.562-674G>A | Intron (SNP) | VAF 9/53 reads (17%) | catalogued as rs750346875; called by muse, mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.1866-12764C>A | Intron (SNP) | VAF 4/35 reads (11%) | called by mutect2, varscan2
- SNX29 | c.247+2227A>G | Intron (SNP) | VAF 4/30 reads (13%) | catalogued as rs1321905904; called by muse, mutect2
- STXBP1 | chr9:127695095 G>A | 3'Flank (SNP) | VAF 10/74 reads (14%) | catalogued as rs752127970, COSV58852685; called by muse, varscan2
- TAP1 | c.*41C>G | 3'UTR (SNP) | VAF 11/70 reads (16%) | called by muse, mutect2, varscan2
- TPCN1 | c.-48_-47del | 5'UTR (DEL) | VAF 6/84 reads (7%) | called by mutect2, pindel
